Somatic mutation profile of tumor specimen TCGA-D9-A148-06A (aliquot TCGA-D9-A148-06A-11D-A19A-08) from TCGA case TCGA-D9-A148, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D9-A148-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb7af7af-0a5f-486e-a1f3-4b656c9031a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A148-10A (Blood Derived Normal), aliquot TCGA-D9-A148-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abf2399a-1b45-417f-9323-1725ff60d0e1

The open-access MAF lists 327 somatic variants for this specimen: 213 protein-altering or splice-affecting, 107 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 107, Nonsense Mutation 11, Splice Site 5, Frame Shift Del 4, RNA 3, Frame Shift Ins 2, Splice Region 2, 3'Flank 2, 5'UTR 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GNE | c.1009C>T p.R337* (on ENST00000396594 / NM_001128227.3; = p.R306* on NM_005476.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/151 reads (54%) | catalogued as rs1057516374, CM156982, COSV64952224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15535C>T p.R5179C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs794727688, CM1410247, COSV56425613, COSV56431676; ClinVar: pathogenic; called by mutect2, varscan2
- USP9X | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs869025592, CM161665, COSV61071116; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABL1 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59334114; called by muse, mutect2, varscan2
- AC098582.1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52021591; called by muse, mutect2, varscan2
- ACSL6 | c.1030T>C p.F344L (on ENST00000379240; = p.F369L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV57300430; called by muse, mutect2, varscan2
- ADGRB3 | c.3571G>A p.D1191N | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53235644; called by muse, mutect2, varscan2
- ADGRV1 | c.13877A>T p.K4626I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as COSV67988279; called by mutect2, varscan2
- ADH1A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52925337; called by muse, mutect2, varscan2
- AGL | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs777099171, COSV99649950; called by muse, mutect2, varscan2
- ALDH1A2 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51083714; called by mutect2, varscan2
- ALMS1 | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 122/178 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV52513095; called by muse, mutect2, varscan2
- APCS | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as COSV54817792; called by muse, mutect2, varscan2
- AQP3 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs751533899, COSV53048556; called by muse, mutect2, varscan2
- ARFGEF3 | c.3888G>A p.W1296* | Nonsense Mutation (SNP) | VAF 41/120 reads (34%) | catalogued as COSV52461143; called by muse, mutect2, varscan2
- ARHGAP33 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV50127863; called by mutect2, varscan2
- ARNT2 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV57587049; called by muse, mutect2, varscan2
- ASCC2 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs371998433; called by muse, varscan2
- ASNSD1 | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53624049; called by mutect2, varscan2
- ATP13A3 | c.3235A>T p.I1079F | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV55466020; called by muse, mutect2, varscan2
- ATP8B2 | c.2083C>T p.L695F (on ENST00000672630; = p.L662F on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs1174910262, COSV59246698; called by muse, mutect2, varscan2
- BLNK | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 58/118 reads (49%) | catalogued as COSV56412057; called by muse, mutect2, varscan2
- BMP5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147691986; called by mutect2, varscan2
- BSG | c.1070-1G>A p.X357_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | catalogued as COSV61077518; called by muse, mutect2, varscan2
- BTD | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs747489101, COSV57729515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C2orf78 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV68518166; called by muse, mutect2, varscan2
- C6orf15 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99457152; called by muse, varscan2
- CAMSAP2 | c.2020C>T p.P674S (on ENST00000236925 / NM_001297707.2; = p.P663S on NM_203459.3) | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866124359, COSV52672835; called by muse, mutect2, varscan2
- CAP2 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV57733685; called by muse, mutect2, varscan2
- CCDC38 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV60183634; called by muse, mutect2, varscan2
- CD2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV65644445; called by muse, mutect2, varscan2
- CD300A | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV60410429; called by muse, mutect2, varscan2
- CDC42EP3 | c.348A>T p.Q116H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54874748; called by muse, mutect2, varscan2
- COL20A1 | c.3410G>A p.R1137K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV58919716; called by muse, mutect2, varscan2
- COL4A2 | c.3281G>A p.G1094E | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847461; called by muse, mutect2, varscan2
- CRIM1 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54866711; called by muse, mutect2, varscan2
- CYTH1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs771108245, COSV63121474; called by mutect2, varscan2
- DCLK3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs746230526, COSV69362234; called by muse, mutect2, varscan2
- DDX18 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV54307349; called by muse, mutect2, varscan2
- DDX39B | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100795268; called by muse, mutect2, varscan2
- DDX3X | c.1232C>T p.S411F (on ENST00000399959; = p.S412F on NM_001356.5) | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV67863397; called by muse, mutect2, varscan2
- DDX42 | c.1429A>G p.I477V | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1315361243, COSV63790478; called by muse, mutect2
- DNAH5 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749610202, COSV54203222; called by mutect2, varscan2
- DNAH7 | c.9745G>A p.E3249K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.26); catalogued as rs1410441318, COSV56751130; called by muse, mutect2, varscan2
- DNMT3A | c.1677C>G p.C559W | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53045515; called by muse, mutect2, varscan2
- DNMT3A | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as rs1167876410, COSV53060582; called by muse, mutect2, varscan2
- DYNC2H1 | c.987A>T p.K329N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV62097564; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61080452; called by muse, mutect2, varscan2
- EMILIN2 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.434); catalogued as COSV54424910; called by muse, mutect2, varscan2
- EPO | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV53161677; called by mutect2, varscan2
- ERICH3 | c.3674G>A p.G1225E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV58610360; called by muse, mutect2, varscan2
- FAM83A | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs930921256, COSV52685969; called by muse, mutect2, varscan2
- FCMR | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65568225; called by muse, mutect2, varscan2
- FCN2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs757338211, COSV52477496; called by muse, varscan2
- FNIP1 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs13177318, COSV57197624; called by muse, mutect2, varscan2
- FOXR2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV59258934; called by muse, mutect2, varscan2
- GABRG2 | c.982G>A p.V328I (on ENST00000361925 / NM_001375343.1; = p.V288I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/142 reads (73%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.983); catalogued as rs768565280, COSV62719273; called by muse, mutect2, varscan2
- GAL3ST1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs375791748; called by muse, varscan2
- GALNT17 | c.1669-1G>A p.X557_splice | Splice Site (SNP) | VAF 51/102 reads (50%) | catalogued as COSV61168513; called by muse, mutect2, varscan2
- GIMAP8 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.079); catalogued as COSV56232256; called by muse, mutect2, varscan2
- GORASP2 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV52202638; called by muse, mutect2, varscan2
- GPI | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62894284; called by muse, mutect2, varscan2
- GPR155 | c.2147A>T p.H716L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV55039806; called by muse, mutect2, varscan2
- GRN | c.1496T>G p.V499G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV50007621; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57031379; called by muse, mutect2, varscan2
- HAPLN1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57149191; called by muse, mutect2, varscan2
- HEG1 | c.4034G>A p.G1345E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100230884; called by muse, mutect2, varscan2
- HHATL | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765197293, COSV55132823; called by mutect2, varscan2
- HIPK4 | c.1249_1251del p.E417del | In Frame Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs769433752; called by pindel, varscan2
- HTRA1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64564525; called by muse, mutect2, varscan2
- ICA1L | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538163431, COSV64173803, COSV64175755; called by muse, mutect2, varscan2
- IDE | c.1245G>A p.K415= | Splice Region (SNP) | VAF 193/389 reads (50%) | catalogued as COSV56424689; called by muse, mutect2, varscan2
- IGLL5 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV66537945; called by muse, mutect2, varscan2
- IGLV3-21 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs749610790; called by mutect2, varscan2
- INHBA | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54222628; called by muse, mutect2, varscan2
- INSR | c.3408G>T p.M1136I | Missense Mutation (SNP) | VAF 86/384 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs776740574, CD972279, COSV57165347; called by muse, varscan2
- IQCH | c.1505A>C p.E502A | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60055080; called by muse, mutect2, varscan2
- IQGAP2 | c.4653G>A p.M1551I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV57175980; called by mutect2, varscan2
- ISX | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs267606235, COSV58087168; called by muse, mutect2, varscan2
- ITGB2 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100186104; called by muse, mutect2, varscan2
- ITGB4 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52328498; called by muse, mutect2, varscan2
- KCNH7 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV59801082; called by muse, mutect2, varscan2
- KCNK9 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs1237927464, COSV57278660; called by mutect2, varscan2
- KCNQ3 | c.2467G>A p.G823R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.329); catalogued as rs1563761293, COSV66473767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1217 | c.1855G>A p.G619R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56818654; called by mutect2, varscan2
- KIAA1755 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 115/374 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV54073440, COSV99642089; called by muse, mutect2, varscan2
- KIF12 | c.991G>A p.G331R (on ENST00000640217; = p.G193R on NM_138424.1) | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV65117563; called by muse, mutect2, varscan2
- KIF1C | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57905213; called by muse, mutect2, varscan2
- KIF25 | c.1028G>A p.S343N (on ENST00000354419 / NM_030615.2; = p.S291N on NM_005355.3) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.149); catalogued as COSV63027771; called by muse, mutect2, varscan2
- KMT2D | c.13267C>T p.P4423S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56454599, COSV56454710; called by muse, mutect2, varscan2
- KRT12 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV52430300; called by muse, mutect2, varscan2
- KRT2 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.406); catalogued as rs1337082248, COSV59011139; called by muse, mutect2
- LINGO4 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 101/175 reads (58%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.474); catalogued as COSV63215084; called by muse, mutect2, varscan2
- LLCFC1 | c.404G>A p.G135E (on ENST00000458732; = p.G104E on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs769981543, COSV62335861; called by muse, mutect2, varscan2
- LRCH2 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57753247; called by mutect2, varscan2
- LRP1B | c.6122G>A p.W2041* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV67236792, COSV67238175; called by muse, varscan2
- LRRC56 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV54243041; called by mutect2, varscan2
- LRRK1 | c.1963del p.L655Wfs*107 | Frame Shift Del (DEL) | VAF 13/98 reads (13%) | catalogued as COSV52613854; called by mutect2, pindel, varscan2
- MAGED1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV58515718; called by muse, mutect2, varscan2
- MAP11 | c.765T>G p.D255E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV57586834; called by muse, mutect2, varscan2
- MAP3K19 | c.3412A>G p.I1138V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59640104; called by muse, mutect2, varscan2
- MED12L | c.2624A>C p.Y875S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56384025; called by muse, varscan2
- MED12L | c.2690A>T p.N897I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56384037; called by muse, varscan2
- MFSD6L | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs183226947; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3410C>T p.S1137F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV56621052; called by muse, mutect2, varscan2
- MTTP | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV55507145; called by muse, mutect2, varscan2
- MUC16 | c.7969C>G p.P2657A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV67475639; called by muse, mutect2, varscan2
- MUC16 | c.7177C>T p.P2393S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67475641; called by muse, mutect2, varscan2
- MXRA5 | c.2585G>A p.S862N | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54239708; called by muse, mutect2, varscan2
- MYB | c.1567C>A p.L523M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV57199131; called by muse, mutect2, varscan2
- MYO9A | c.3406C>T p.Q1136* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV61853190; called by muse, mutect2, varscan2
- NANOG | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV57551750; called by muse, mutect2, varscan2
- NAV1 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55220164; called by muse, mutect2, varscan2
- NBEA | c.3373G>A p.D1125N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV59796072; called by muse, mutect2, varscan2
- NELL1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as COSV54280745; called by muse, mutect2, varscan2
- NPHS1 | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV100800218; called by muse, mutect2, varscan2
- NPTXR | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV60728658; called by mutect2, varscan2
- NRXN3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100202250; called by mutect2, varscan2
- NYAP2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as rs747528697, COSV56009075; called by muse, mutect2
- OR10A7 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV58277727; called by mutect2, varscan2
- OR52E2 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs867332934, COSV58612883; called by muse, mutect2, varscan2
- OR5B3 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV58676555, COSV58676778, COSV58677239; called by muse, mutect2, varscan2
- OR5R1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV56571496; called by muse, mutect2, varscan2
- OTUD7A | c.1163G>A p.R388K (on ENST00000307050 / NM_001382637.1; = p.R381K on NM_130901.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as COSV61040129; called by muse, mutect2, varscan2
- PCDHA7 | c.2248T>C p.F750L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100970980; called by muse, mutect2, varscan2
- PCDHAC1 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53856087; called by muse, mutect2, varscan2
- PCDHB16 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV53364561; called by muse, mutect2, varscan2
- PCDHGA1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs868694812, COSV65297335, COSV65298767; called by muse, mutect2, varscan2
- PDK2 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1472283696, COSV50304009; called by mutect2, varscan2
- PDK3 | c.469A>G p.N157D | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV64793685; called by muse, mutect2, varscan2
- PDZD7 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV56520330; called by muse, mutect2, varscan2
- PDZRN4 | c.2730C>G p.I910M (on ENST00000402685 / NM_001164595.2; = p.I652M on NM_013377.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV54205947; called by muse, mutect2, varscan2
- PEAK1 | c.3536G>A p.S1179N | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV56938183; called by muse, mutect2, varscan2
- PIF1 | c.1751G>C p.R584P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51422907; called by muse, mutect2, varscan2
- PIGV | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 81/129 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as COSV50292921; called by muse, mutect2, varscan2
- POLR1B | c.3253C>G p.P1085A | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as COSV54499924; called by muse, mutect2, varscan2
- POU1F1 | c.810A>C p.K270N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55462772; called by muse, mutect2, varscan2
- PPP3CA | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV59925879; called by muse, mutect2, varscan2
- PREX2 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs775560862, COSV55751823; called by muse, mutect2, varscan2
- PRIMPOL | c.1562A>C p.Y521S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV55658167; called by muse, mutect2, varscan2
- PRPF40B | c.99dup p.M34Hfs*67 (on ENST00000380281; = p.M28Hfs*67 on NM_012272.3) | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | catalogued as rs780675733; called by mutect2, varscan2
- PRRC2C | c.5049T>G p.F1683L (on ENST00000367742; = p.F1681L on NM_015172.4) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58902329; called by muse, mutect2
- PTK2B | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57755373; called by muse, mutect2, varscan2
- RAB11FIP3 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs759675366, COSV51934824; called by muse, mutect2, varscan2
- RASA2 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.077); catalogued as COSV53942121; called by muse, mutect2, varscan2
- RBM26 | c.1787A>T p.N596I | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57396243; called by muse, mutect2, varscan2
- RCL1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as rs188571643, COSV67755869; called by muse, mutect2, varscan2
- RFX6 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.053); catalogued as rs372382597; called by muse, varscan2
- RFX7 | c.2776C>T p.P926S (on ENST00000559447 / NM_001368074.1; = p.P1023S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57965468; called by muse, mutect2, varscan2
- RGS22 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756666569, COSV62663608; called by muse, mutect2, varscan2
- RHOV | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); catalogued as COSV55027711; called by muse, mutect2, varscan2
- RNF112 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101518360; called by mutect2, varscan2
- RPAP1 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58540369; called by muse, mutect2, varscan2
- RUSF1 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV57892535; called by muse, mutect2, varscan2
- SCFD1 | c.1905+2T>C p.X635_splice | Splice Site (SNP) | VAF 37/63 reads (59%) | catalogued as COSV61724824; called by muse, mutect2, varscan2
- SCN9A | c.2491T>G p.L831V (on ENST00000303354; = p.L820V on NM_002977.3) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV57614018; called by muse, mutect2, varscan2
- SDK1 | c.3402G>T p.E1134D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV67375183; called by muse, mutect2, varscan2
- SDR16C5 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV58126999; called by muse, mutect2, varscan2
- SDR16C5 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV58126416; called by mutect2, varscan2
- SERPINB2 | c.1247A>T p.*416Lext*2 | Nonstop Mutation (SNP) | VAF 10/14 reads (71%) | catalogued as COSV53073799; called by mutect2, varscan2
- SETD1A | c.2390T>A p.M797K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52689335; called by muse, mutect2, varscan2
- SINHCAF | c.130T>C p.L44= | Splice Region (SNP) | VAF 14/76 reads (18%) | catalogued as COSV61797450; called by muse, mutect2, varscan2
- SIPA1 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100425917; called by muse, mutect2, varscan2
- SIPA1 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100425918; called by muse, mutect2, varscan2
- SLC24A4 | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV54114025; called by muse, mutect2, varscan2
- SLC25A42 | c.44A>C p.D15A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs571380861, COSV59380703; called by muse, mutect2, varscan2
- SLC3A1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 76/102 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs139377923; called by muse, mutect2, varscan2
- SLTM | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV51055150; called by muse, mutect2, varscan2
- SMARCAL1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 145/192 reads (76%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs754343294, COSV61921769; called by muse, mutect2, varscan2
- SMC1B | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 131/210 reads (62%) | catalogued as COSV62530808, COSV62531360; called by muse, mutect2, varscan2
- SNUPN | c.827G>C p.W276S | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57948778; called by muse, mutect2, varscan2
- SORCS3 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63803272; called by muse, mutect2, varscan2
- SORCS3 | c.3133C>T p.L1045F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100865153, COSV100865640, COSV63830189; called by muse, mutect2, varscan2
- SRL | c.611-1G>A p.X204_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV101281368; called by muse, mutect2, varscan2
- STK31 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV63457268; called by muse, mutect2, varscan2
- SYNE1 | c.7345C>G p.L2449V (on ENST00000367255 / NM_182961.4; = p.L2456V on NM_033071.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV55017960; called by muse, mutect2, varscan2
- SYNGAP1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV53382804; called by muse, mutect2, varscan2
- TAF1L | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV54263823; called by muse, mutect2, varscan2
- TBC1D1 | c.2072T>A p.L691H | Missense Mutation (SNP) | VAF 104/128 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV54721603; called by muse, mutect2, varscan2
- TINF2 | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57469413; called by mutect2, varscan2
- TMEM17 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs755900951, COSV100107635, COSV59022671; called by mutect2, varscan2
- TNN | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV53429002; called by muse, mutect2, varscan2
- TNNI3K | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.996); catalogued as rs971911939, COSV53947677, COSV53949680; called by muse, mutect2, varscan2
- TOMM40L | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63468422; called by muse, mutect2, varscan2
- TRAV2 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 116/175 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs1555343401; called by muse, mutect2, varscan2
- TRAV26-2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs764083567; called by mutect2, varscan2
- TRPM6 | c.2449G>A p.G817S | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV62514523; called by muse, mutect2, varscan2
- TTN | c.25401G>A p.W8467* (on ENST00000591111; = p.W7540* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100612318; called by muse, mutect2, varscan2
- TUBA1B | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100254209; called by muse, mutect2, varscan2
- TWIST1 | c.550A>G p.S184G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV54251050; called by muse, mutect2
- UFM1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as rs1566029075, COSV53495760; called by muse, mutect2, varscan2
- ULK4 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.815); catalogued as COSV57212935; called by muse, mutect2, varscan2
- VCP | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV62721205; called by muse, varscan2
- VPS53 | c.1945G>A p.V649I (on ENST00000571805 / NM_001366253.2; = p.V620I on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.217); catalogued as rs776271570, COSV52132478; called by mutect2, varscan2
- VTN | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99879806; called by muse, varscan2
- WNT7A | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53199910; called by muse, mutect2, varscan2
- ZBBX | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56789847; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV54297367; called by muse, mutect2, varscan2
- ZDBF2 | c.5615G>A p.G1872E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65627348; called by muse, mutect2, varscan2
- ZFP64 | c.1813A>G p.T605A | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1019631807, COSV53800817; called by muse, mutect2, varscan2
- ZFP90 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68050648; called by muse, mutect2, varscan2
- ZNF235 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs768594165, COSV52157082; called by mutect2, varscan2
- ZNF335 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV59818478; called by muse, mutect2, varscan2
- ZNF518B | c.2504T>C p.M835T | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs771241037, COSV58723224, COSV58723969; called by muse, mutect2, varscan2
- ZNF614 | c.93C>A p.N31K | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV54544623, COSV99571949; called by muse, mutect2, varscan2
- ZNF831 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV64041767; called by muse, mutect2, varscan2
- ZPLD1 | c.527C>T p.S176F (on ENST00000466937 / NM_001329788.1; = p.S192F on NM_175056.2) | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV60354442; called by muse, mutect2, varscan2
- AP5Z1 | c.298dup p.S100Kfs*25 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- GLT8D1 | c.189_205del p.Q63Hfs*6 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- NFIB | c.899del p.S300Ifs*17 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- TRPM6 | c.422_423del p.S141Cfs*13 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- A3GALT2 | c.78C>T p.G26= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1416636773, COSV57760995; called by muse, mutect2
- ABCC11 | c.2460G>A p.T820= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as rs754221632, COSV62324062; called by mutect2, varscan2
- ADGRB2 | c.451C>T p.L151= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV57075341; called by muse, mutect2, varscan2
- ADGRG4 | c.2091C>T p.S697= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as rs748146182, COSV54957399; called by muse, mutect2, varscan2
- AGL | c.2688C>T p.A896= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs1165777431, COSV99649953; called by muse, mutect2, varscan2
- AHRR | c.1797G>A p.R599= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV57088313; called by muse, mutect2
- AKAP6 | c.5142G>A p.S1714= | Silent (SNP) | VAF 46/66 reads (70%) | catalogued as rs1178024502, COSV55206312; called by mutect2, varscan2
- ANO2 | c.2328C>T p.L776= (on ENST00000356134 / NM_001278597.3; = p.L780= on NM_001278596.3) | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs201702934; called by mutect2, varscan2
- APCS | c.75G>A p.G25= | Silent (SNP) | VAF 45/68 reads (66%) | catalogued as rs979861757, COSV54817406, COSV54818517; called by muse, mutect2, varscan2
- AQP5 | c.84C>T p.G28= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99527542; called by muse, mutect2, varscan2
- AQP5 | c.85C>T p.L29= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99527544; called by muse, mutect2, varscan2
- ARAP3 | c.1500C>T p.A500= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV53351687; called by muse, mutect2, varscan2
- ARMC4 | c.3087C>T p.S1029= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV59466155; called by muse, mutect2, varscan2
- ASXL2 | c.768C>G p.L256= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV55461165; called by muse, mutect2, varscan2
- C6 | c.879C>T p.I293= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs1313242644, COSV54709963, COSV54717415; called by muse, mutect2, varscan2
- CACNA1G | c.2730C>T p.L910= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV61730881; called by muse, varscan2
- CASS4 | c.1500C>T p.V500= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as COSV64387065; called by muse, mutect2, varscan2
- CCDC185 | c.1416C>T p.R472= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1274621191, COSV64821197; called by mutect2, varscan2
- CCDC71 | c.651G>A p.G217= | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as COSV58910375; called by muse, varscan2
- CCDC74A | c.894C>T p.S298= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV54607688, COSV99723826; called by muse, mutect2, varscan2
- CCDC83 | c.585G>A p.K195= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV54699631, COSV54702797; called by muse, mutect2, varscan2
- CDH18 | c.1648C>T p.L550= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV56933164, COSV99933589; called by muse, mutect2, varscan2
- CDR1 | c.228G>A p.R76= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV65164426; called by muse, mutect2, varscan2
- CHD5 | c.4770G>A p.L1590= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV52417926; called by muse, mutect2, varscan2
- CLCA2 | c.1357C>T p.L453= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV65287192, COSV65287704; called by muse, mutect2, varscan2
- CLEC4M | c.321C>T p.S107= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV50220200; called by muse, varscan2
- CNTN2 | c.1506C>T p.I502= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs1186028093, COSV100085411; called by muse, mutect2, varscan2
- CNTN2 | c.1507C>T p.L503= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs766723952, COSV100085414; called by muse, mutect2, varscan2
- COL6A6 | c.396C>T p.P132= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV62028798; called by muse, mutect2, varscan2
- CT55 | c.531G>A p.T177= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV52277878, COSV99358990; called by muse, mutect2, varscan2
- CUZD1 | c.304C>T p.L102= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as COSV59027106; called by muse, mutect2, varscan2
- DACH1 | c.783G>A p.V261= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as COSV57506263, COSV57514006; called by muse, mutect2, varscan2
- DCD | c.24C>T p.F8= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53201158; called by muse, mutect2, varscan2
- DDX11 | c.1749C>T p.I583= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV52506281; called by muse, mutect2, varscan2
- DDX39B | c.840C>T p.D280= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100795269; called by muse, mutect2, varscan2
- DMBT1 | c.6669C>T p.F2223= (on ENST00000338354 / NM_001377530.1; = p.F1466= on NM_004406.3) | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV57548300; called by mutect2, varscan2
- DNAAF3 | c.1242C>T p.Y414= (on ENST00000524407 / NM_001256715.2; = p.Y461= on NM_178837.4) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV61277710; called by muse, varscan2
- DNAH1 | c.12582G>A p.E4194= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV56236341; called by muse, mutect2, varscan2
- DNAH10 | c.5622G>A p.R1874= (on ENST00000409039; = p.R1813= on NM_207437.3) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV68995958; called by mutect2, varscan2
- DNAH17 | c.9129G>A p.E3043= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV67757170; called by muse, mutect2, varscan2
- DSP | c.6039G>A p.R2013= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV65791597, COSV65793566; called by muse, mutect2, varscan2
- DUOXA1 | c.216C>T p.F72= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV50993922; called by muse, mutect2, varscan2
- ETV1 | c.1260C>T p.A420= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1562576304, COSV54144871; called by muse, mutect2, varscan2
- EYA2 | c.1530G>A p.A510= | Silent (SNP) | VAF 57/98 reads (58%) | catalogued as rs760562862, COSV57945732; called by muse, mutect2, varscan2
- FAM171B | c.2227C>T p.L743= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV59004953; called by muse, mutect2, varscan2
- FAM181A | c.558G>A p.Q186= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV50887815; called by muse, mutect2, varscan2
- FN1 | c.858C>T p.F286= | Silent (SNP) | VAF 147/197 reads (75%) | catalogued as rs200009831, COSV60556063; called by muse, mutect2, varscan2
- GAL3ST1 | c.24C>T p.P8= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as COSV100143220; called by muse, varscan2
- HDAC7 | c.1128C>T p.P376= (on ENST00000427332; = p.P415= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV50318448; called by muse, mutect2, varscan2
- IFITM3 | c.72G>A p.K24= | Silent (SNP) | VAF 55/126 reads (44%) | catalogued as rs1449303750, COSV67707183; called by muse, mutect2, varscan2
- IGFN1 | c.3480G>A p.L1160= (on ENST00000295591 / NM_001367841.1; = p.L3617= on NM_001164586.2) | Silent (SNP) | VAF 65/95 reads (68%) | catalogued as COSV55175643; called by muse, mutect2, varscan2
- ILF3 | c.1767C>T p.F589= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs565885328, COSV51555504; called by muse, mutect2, varscan2
- ITGB2 | c.483C>T p.T161= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs750060536, COSV100186103; ClinVar: uncertain significance; called by mutect2, varscan2
- KMT2D | c.15534C>T p.F5178= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99985337; called by muse, mutect2, varscan2
- LMX1A | c.678G>A p.E226= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV54223108; called by muse, mutect2, varscan2
- LRP1B | c.1734C>T p.F578= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV67216995; called by mutect2, varscan2
- LRP6 | c.1329G>A p.E443= | Silent (SNP) | VAF 157/408 reads (38%) | catalogued as COSV53789532; called by muse, mutect2, varscan2
- MGAM | c.5475C>T p.F1825= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV72074951; called by mutect2, varscan2
- MYO18B | c.2715G>A p.V905= | Silent (SNP) | VAF 47/216 reads (22%) | catalogued as rs757963685, COSV59138470; called by muse, varscan2
- MYO3B | c.1851C>T p.F617= | Silent (SNP) | VAF 66/146 reads (45%) | catalogued as rs371681489; called by muse, mutect2, varscan2
- NCR1 | c.123G>A p.K41= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs754249586, COSV52557189; called by muse, mutect2, varscan2
- NDUFAF5 | c.273C>T p.P91= | Silent (SNP) | VAF 47/64 reads (73%) | catalogued as rs757439081, COSV52522031; called by muse, mutect2, varscan2
- NIPBL | c.5557C>T p.L1853= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV56956041; called by muse, mutect2, varscan2
- NLRP7 | c.483G>A p.L161= | Silent (SNP) | VAF 90/177 reads (51%) | catalogued as COSV60176599; called by muse, mutect2, varscan2
- NOP9 | c.936C>T p.S312= | Silent (SNP) | VAF 60/102 reads (59%) | catalogued as rs750136966, COSV51866452; called by muse, mutect2, varscan2
- NPHS1 | c.2310G>A p.P770= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs1390523402, COSV100800219; called by muse, varscan2
- OBSCN | c.10899G>A p.R3633= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV52788044, COSV99483842; called by muse, mutect2, varscan2
- OGDHL | c.690G>A p.V230= | Silent (SNP) | VAF 55/121 reads (45%) | catalogued as COSV65103261; called by mutect2, varscan2
- OR4D9 | c.699G>A p.R233= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as rs1565094090, COSV61434911; called by muse, mutect2, varscan2
- OR51E2 | c.501C>T p.F167= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV67807829, COSV67808271; called by muse, mutect2, varscan2
- OR8B12 | c.924C>T p.I308= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- OS9 | c.1749G>A p.E583= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV57729327; called by muse, mutect2, varscan2
- PCDHGA11 | c.228C>T p.F76= | Silent (SNP) | VAF 37/54 reads (69%) | catalogued as rs762490406, COSV53916754; called by muse, mutect2, varscan2
- PCLO | c.5088G>A p.E1696= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV61637232, COSV61644093; called by muse, mutect2, varscan2
- PDIA3 | c.435T>C p.F145= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV55857025; called by muse, mutect2, varscan2
- PELI2 | c.468C>T p.F156= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs371989404; called by mutect2, varscan2
- PFKFB4 | c.1044C>T p.F348= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1206946410, COSV51680357; called by mutect2, varscan2
- PHACTR3 | c.1224G>A p.R408= | Silent (SNP) | VAF 148/269 reads (55%) | catalogued as COSV63029954; called by muse, mutect2, varscan2
- PHF21A | c.192A>C p.V64= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV57655836; called by muse, mutect2, varscan2
- PI4KA | c.4020C>T p.N1340= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1374030412, COSV55414543; called by mutect2, varscan2
- PIK3C2B | c.2958G>A p.L986= | Silent (SNP) | VAF 80/144 reads (56%) | catalogued as rs1490485253, COSV100915978, COSV65810211, COSV65812471; called by muse, mutect2, varscan2
- PIK3CA | c.915A>T p.P305= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV55943457; called by muse, mutect2, varscan2
- PKHD1L1 | c.10386G>A p.G3462= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs868846402, COSV65737764; called by muse, mutect2, varscan2
- PKP2 | c.2589G>A p.K863= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs777477467, COSV50726605; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLSCR2 | c.861C>T p.L287= (on ENST00000497985 / NM_001199978.1; = p.L214= on NM_020359.2) | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as COSV60862094; called by muse, mutect2, varscan2
- PML | c.345C>T p.R115= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs753820877, COSV51448704; called by muse, mutect2, varscan2
- RANBP6 | c.2322C>T p.L774= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV52390102; called by muse, mutect2, varscan2
- RAPSN | c.243C>T p.F81= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV54084856; called by mutect2, varscan2
- RELN | c.7335C>T p.L2445= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1228886851, COSV59011777; called by muse, mutect2, varscan2
- RNF112 | c.210G>A p.L70= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV101518359; called by mutect2, varscan2
- RSPH3 | c.1380C>T p.I460= (on ENST00000252655; = p.I318= on NM_031924.8) | Silent (SNP) | VAF 57/94 reads (61%) | catalogued as rs267600878, COSV51923168; called by muse, mutect2, varscan2
- SDK2 | c.4686C>T p.A1562= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV66189145; called by muse, mutect2, varscan2
- SDK2 | c.4128G>A p.T1376= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs370430999, COSV66182768; called by muse, mutect2, varscan2
- SELENOS | c.432C>T p.S144= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV68011367; called by muse, mutect2, varscan2
- SLC22A16 | c.846C>T p.I282= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV57931192; called by muse, mutect2, varscan2
- SLC24A3 | c.192G>A p.A64= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as rs556701714, COSV60123047; called by mutect2, varscan2
- SLC6A3 | c.295C>T p.L99= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV54365640; called by muse, mutect2, varscan2
- STARD10 | c.195G>A p.L65= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as COSV58325968; called by mutect2, varscan2
- TRANK1 | c.3051G>A p.V1017= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as COSV57154340; called by muse, mutect2, varscan2
- TSSC4 | c.630G>A p.E210= | Silent (SNP) | VAF 116/311 reads (37%) | catalogued as COSV50159295; called by muse, mutect2, varscan2
- USP44 | c.780C>T p.S260= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs564508849, COSV51564950; called by muse, mutect2, varscan2
- VTN | c.324G>A p.G108= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1478267398, COSV99879805; called by muse, varscan2
- ZNF213 | c.90G>A p.Q30= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV67727932; called by muse, mutect2, varscan2
- ZNF614 | c.94C>T p.L32= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV99571947; called by muse, mutect2, varscan2
- ZNF776 | c.1167C>T p.S389= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV57815579; called by muse, mutect2, varscan2
- ZNF799 | c.180G>A p.R60= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV70122830; called by muse, mutect2, varscan2
- ZNF862 | c.174C>T p.F58= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs767113245, COSV56223968; called by muse, mutect2, varscan2
- AL163540.1 | n.312T>C | RNA (SNP) | VAF 108/191 reads (57%) | called by muse, mutect2, varscan2
- ARPP21 | c.2032+520G>A | Intron (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99493092; called by muse, mutect2, varscan2
- CD2 | c.-1G>A | 5'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as COSV101040186; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271789 G>A | 3'Flank (SNP) | VAF 52/132 reads (39%) | catalogued as rs776575895; called by muse, mutect2, varscan2
- DCHS2 | n.6397C>T | RNA (SNP) | VAF 19/31 reads (61%) | catalogued as COSV61774230; called by muse, mutect2, varscan2
- FXYD6P3 | n.119G>A | RNA (SNP) | VAF 23/28 reads (82%) | called by muse, mutect2, varscan2
- ZSCAN32 | chr16:3382960 C>G | 3'Flank (SNP) | VAF 15/66 reads (23%) | catalogued as rs372402522, COSV59235830; called by muse, mutect2, varscan2
